Somatic mutation profile of tumor specimen TARGET-20-PARLSW-09A (aliquot TARGET-20-PARLSW-09A-02D) from TARGET case TARGET-20-PARLSW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,906 days).
Specimen TARGET-20-PARLSW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 540c97c5-9dd3-4fdf-85e2-26913688066a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLSW-14A (Bone Marrow Normal), aliquot TARGET-20-PARLSW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3da3c7ec-198c-420d-91bd-561f72d6419c

The open-access MAF lists 3 somatic variants for this specimen: 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.3384G>A p.T1128= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs770311284; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCLO | c.*909C>T | 3'UTR (SNP) | VAF 145/302 reads (48%) | called by muse, mutect2, varscan2
- REPS2 | c.*2338C>T | 3'UTR (SNP) | VAF 106/240 reads (44%) | catalogued as rs1424231691; called by muse, mutect2, varscan2
